Somatic mutation profile of tumor specimen CDDP-ABLE-TTP1-B (aliquot CDDP-ABLE-TTP1-B-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABLE, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 53 years.
Specimen CDDP-ABLE-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ed993a7-9269-4d2f-9289-eefa4c7669f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABLE-NB1-A (Blood Derived Normal), aliquot CDDP-ABLE-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73e9f2f9-f2df-4f9e-859d-c35ec67147f2

The open-access MAF lists 529 somatic variants for this specimen: 339 protein-altering or splice-affecting, 123 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 295, Silent 123, Intron 30, Nonsense Mutation 21, RNA 17, Splice Site 9, 3'UTR 8, 5'UTR 8, Frame Shift Del 8, 5'Flank 3, Frame Shift Ins 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 87/256 reads (34%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, mutect2, varscan2
- KCNH2 | c.1750G>T p.G584C | Missense Mutation (SNP) | VAF 63/338 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199473428, CM001201, CM085487, CM097452; ClinVar: pathogenic / not provided / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 65/225 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASS | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs762873545, COSV62788607, COSV62790642; called by muse, mutect2, varscan2
- ABCA3 | c.3934G>C p.A1312P | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV57057215; called by muse, mutect2, varscan2
- ABL2 | c.1739G>T p.R580L (on ENST00000502732 / NM_007314.4; = p.R565L on NM_005158.5) | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as COSV61013084; called by muse, mutect2, varscan2
- ADAM19 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57433129, COSV99976106; called by muse, mutect2, varscan2
- ADCY8 | c.2728C>A p.L910M | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV99655030; called by muse, mutect2, varscan2
- ADGRV1 | c.15262G>T p.E5088* | Nonsense Mutation (SNP) | VAF 34/213 reads (16%) | catalogued as COSV67980148; called by muse, mutect2, varscan2
- AFTPH | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.709); catalogued as rs746871941; called by muse, mutect2, varscan2
- AKT2 | c.1092G>C p.M364I | Missense Mutation (SNP) | VAF 147/424 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV60909331; called by muse, mutect2, varscan2
- ARHGAP21 | c.3309G>T p.E1103D | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV57606829; called by muse, mutect2
- ATP4A | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 54/306 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as rs770629738, COSV52866954; called by muse, mutect2, varscan2
- BTG3 | c.59A>G p.D20G | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV60286688; called by muse, mutect2, varscan2
- CCDC27 | c.791C>G p.A264G | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV53900680; called by muse, mutect2, varscan2
- CCR4 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV58384313; called by muse, mutect2, varscan2
- CCT7 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV54584750; called by muse, mutect2, varscan2
- CDH4 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.971); catalogued as rs757336738, COSV64650871; called by muse, mutect2, varscan2
- CFHR1 | c.273del p.F91Lfs*40 | Frame Shift Del (DEL) | VAF 50/368 reads (14%) | catalogued as rs752101729; called by mutect2, varscan2
- CHRNA4 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 163/658 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758885593; called by muse, mutect2, varscan2
- CHST8 | c.672C>A p.H224Q | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1363442607; called by muse, mutect2, varscan2
- CLGN | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100346825, COSV57775802; called by muse, mutect2, varscan2
- COL11A1 | c.2621del p.G874Afs*108 | Frame Shift Del (DEL) | VAF 84/393 reads (21%) | catalogued as COSV100615919; called by mutect2, pindel, varscan2
- COL4A1 | c.3122G>T p.G1041V | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM130953, COSV65433221; called by muse, mutect2, varscan2
- COL6A3 | c.4709G>A p.S1570N | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as rs1473351823, COSV99796011; called by muse, mutect2
- CREB1 | c.520A>G p.I174V (on ENST00000432329 / NM_134442.5; = p.I160V on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs1245810175; called by muse, mutect2
- CSF2RA | c.1051A>G p.R351G | Missense Mutation (SNP) | VAF 40/348 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100817541; called by muse, varscan2
- CSMD3 | c.7064G>T p.G2355V (on ENST00000297405 / NM_001363185.1; = p.G2251V on NM_052900.3) | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52234786; called by muse, mutect2, varscan2
- CTRC | c.550G>C p.A184P | Missense Mutation (SNP) | VAF 91/332 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV101036487; called by muse, mutect2, varscan2
- DACT1 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV60022593, COSV60023625; called by muse, mutect2
- DNAH17 | c.270C>A p.D90E | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1343446768; called by muse, varscan2
- DSC3 | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs757117351; called by muse, mutect2, varscan2
- DTNB | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs371402432; called by muse, mutect2, varscan2
- ERN2 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1309732987; called by muse, mutect2, varscan2
- ETV6 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as rs762900235, COSV67154149; called by muse, mutect2, varscan2
- EYA4 | c.1459T>A p.L487M (on ENST00000531901 / NM_001301013.1; = p.L481M on NM_004100.5) | Missense Mutation (SNP) | VAF 72/292 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs12663265; called by muse, mutect2, varscan2
- FAM193A | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as rs1163119641; called by muse, varscan2
- FBLN2 | c.1101del p.V368Sfs*74 | Frame Shift Del (DEL) | VAF 66/230 reads (29%) | catalogued as COSV99851348; called by mutect2, pindel*, varscan2
- GIT1 | c.617A>G p.Y206C | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as rs1381752902; called by muse, mutect2, varscan2
- GNB2 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV51943535, COSV51946946; called by muse, mutect2
- GPR135 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs1566550455; called by muse, mutect2
- HMCN1 | c.11492C>G p.P3831R | Missense Mutation (SNP) | VAF 35/422 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54949154; called by muse, mutect2
- IFI44L | c.499G>C p.D167H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.087); catalogued as COSV60727534; called by muse, mutect2, varscan2
- ITIH3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1402435260, COSV69650105; called by muse, mutect2, varscan2
- KHDC4 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as rs1221163150, COSV64164764; called by muse, mutect2
- LAMA2 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 103/350 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70350007; called by muse, mutect2, varscan2
- LHX8 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53955118; called by muse, mutect2, varscan2
- LRBA | c.8207G>T p.G2736V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV100842042; called by muse, mutect2, varscan2
- LRFN5 | c.1502G>T p.R501I | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53264255; called by muse, mutect2, varscan2
- MED1 | c.852G>T p.W284C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs1249780075; called by muse, varscan2
- MED13L | c.6068A>T p.D2023V | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as CM033937, COSV56122001; called by muse, mutect2, varscan2
- MMP2 | c.565G>C p.G189R | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54601462; called by muse, mutect2, varscan2
- MRAP2 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV57631568; called by muse, mutect2, varscan2
- MRPL58 | c.17G>T p.C6F | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs368786552; called by muse, mutect2, varscan2
- MUC17 | c.4220C>T p.P1407L | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs759205801, COSV60284198; called by muse, mutect2, varscan2
- MUC4 | c.4846C>A p.P1616T | Missense Mutation (SNP) | VAF 73/364 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); catalogued as rs563012488, COSV62128698; called by muse, varscan2
- MYH6 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 87/316 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV62449691; called by muse, mutect2, varscan2
- NES | c.1318G>C p.V440L | Missense Mutation (SNP) | VAF 27/335 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV63960446, COSV63963116; called by muse, mutect2
- NRG3 | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV64543166; called by muse, mutect2, varscan2
- OR11L1 | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1306275525, COSV63315223; called by muse, mutect2, varscan2
- OR4K13 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59859659; called by muse, mutect2, varscan2
- OR9A4 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.557); catalogued as COSV71885092; called by muse, mutect2, varscan2
- OR9G4 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265236; called by muse, mutect2, varscan2
- OTOF | c.4922G>T p.R1641L (on ENST00000272371 / NM_194248.3; = p.R874L on NM_004802.4) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs200283244, COSV55516687; called by muse, mutect2, varscan2
- PAF1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 42/508 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs767095758; called by muse, mutect2
- PCDHA7 | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs782550876; called by muse, mutect2, varscan2
- PDILT | c.664G>T p.V222F | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV56701392; called by muse, mutect2, varscan2
- PLA2G5 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.568); catalogued as rs1307460887; called by muse, mutect2, varscan2
- PMS2 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99764244; called by muse, mutect2, varscan2
- POP4 | c.412del p.A138Lfs*5 | Frame Shift Del (DEL) | VAF 20/107 reads (19%) | catalogued as COSV55676541, COSV99694671; called by mutect2, pindel, varscan2
- PPP1R3A | c.2823G>T p.M941I | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs376809464, COSV52883656; called by muse, mutect2, varscan2
- PPP1R3A | c.1697T>A p.L566Q | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs757339496, COSV52876369; called by muse, mutect2, varscan2
- PXYLP1 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 59/532 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201734068, COSV53892056; called by muse, mutect2, varscan2
- RADIL | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.022); catalogued as COSV68201302; called by mutect2, varscan2
- RASIP1 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs369508351; called by muse, mutect2, varscan2
- RFX4 | c.1443G>A p.M481I (on ENST00000392842 / NM_213594.3; = p.M387I on NM_032491.6) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.38); catalogued as COSV57581871; called by muse, mutect2, varscan2
- RNF10 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58044621; called by muse, mutect2, varscan2
- RSBN1L | c.2372A>G p.D791G | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); catalogued as rs1243340930; called by muse, mutect2
- SCN11A | c.5234G>T p.R1745L | Missense Mutation (SNP) | VAF 102/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56567167; called by muse, mutect2, varscan2
- SH2B2 | c.1429G>T p.G477W | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60827874; called by muse, mutect2, varscan2
- SH2D1B | c.32C>A p.T11N | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs1416421587; called by muse, mutect2
- SLC18A2 | c.185C>A p.T62K | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV53694198; called by muse, mutect2, varscan2
- SLC22A10 | c.1029C>A p.N343K | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs774762194; called by muse, mutect2, varscan2
- SLC44A5 | c.1803-1G>T p.X601_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100902444; called by muse, mutect2, varscan2
- SLFN11 | c.523C>A p.Q175K | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.139); catalogued as rs778159998; called by muse, mutect2, varscan2
- SLITRK6 | c.2261C>A p.S754* | Nonsense Mutation (SNP) | VAF 52/170 reads (31%) | catalogued as COSV68390459; called by muse, mutect2, varscan2
- SMOC2 | c.875C>A p.A292D (on ENST00000356284 / NM_001166412.2; = p.A303D on NM_022138.3) | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.123); catalogued as COSV62434969; called by muse, mutect2, varscan2
- STYXL2 | c.2054G>T p.R685L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs370847886; called by muse, mutect2, varscan2
- TFR2 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1189196326; called by muse, mutect2, varscan2
- THSD7B | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295720152; called by muse, mutect2, varscan2
- TPR | c.6547G>T p.G2183C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66599517; called by muse, mutect2, varscan2
- TRBV2 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs753889390; called by muse, mutect2, varscan2
- TRIM38 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 70/256 reads (27%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.602); catalogued as rs199549986; called by muse, varscan2
- TRPV5 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54683807, COSV54689786; called by muse, mutect2, varscan2
- TTN | c.19816G>A p.G6606R (on ENST00000591111; = p.G5679R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | PolyPhen probably damaging (0.992); catalogued as COSV100605839; called by muse, mutect2, varscan2
- WDR87 | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs1413758931, COSV58207514; called by muse, mutect2
- ZFHX3 | c.8300G>A p.G2767E | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.312); catalogued as COSV51707569; called by muse, mutect2, varscan2
- ZIM2 | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs1238828956, COSV55648393; called by muse, mutect2, varscan2
- ZNF44 | c.1897G>T p.E633* (on ENST00000356109 / NM_001164276.2; = p.E585* on NM_016264.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV100633689; called by muse, mutect2, varscan2
- ZNF528 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 93/361 reads (26%) | catalogued as COSV64618900; called by muse, mutect2, varscan2
- ZNF536 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1177918706, COSV100834509; called by muse, varscan2
- ZNF71 | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1418241050, COSV100046229; called by muse, mutect2, varscan2
- ABCA12 | c.2012T>A p.I671K (on ENST00000272895 / NM_173076.3; = p.I353K on NM_015657.3) | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA13 | c.12380G>T p.G4127V | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ABCC5 | c.3331A>T p.T1111S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.041); called by muse, varscan2
- ACRBP | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ADAMTS12 | c.3370A>T p.T1124S | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADCY5 | c.1021A>T p.T341S | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ADCYAP1 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1159G>T p.G387W | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ADGRE1 | c.950G>T p.R317M | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- ADGRG5 | c.533A>T p.H178L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGRN | c.3931C>T p.P1311S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, varscan2
- AKT2 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 145/419 reads (35%) | called by muse, mutect2, varscan2
- ANKDD1B | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ANKEF1 | c.2209A>T p.R737W | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, varscan2
- APBA1 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- ARHGAP5 | c.1897G>T p.D633Y | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- ATP1A2 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 235/354 reads (66%) | SIFT tolerated (0.22); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- B3GNT3 | c.764C>A p.P255Q | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIN2 | c.58A>T p.K20* | Nonsense Mutation (SNP) | VAF 30/136 reads (22%) | called by muse, mutect2, varscan2
- BOD1L1 | c.6689C>T p.S2230F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- BROX | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CAMK2B | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAMSAP2 | c.2536G>T p.A846S (on ENST00000236925 / NM_001297707.2; = p.A835S on NM_203459.3) | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CASKIN2 | c.1654G>T p.A552S | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CASP8AP2 | c.2842C>T p.Q948* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- CCDC150 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCDC168 | c.1924T>C p.C642R | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CCDC173 | c.424A>T p.K142* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | called by muse, varscan2
- CD79B | c.481A>G p.I161V | Missense Mutation (SNP) | VAF 159/627 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CD96 | c.1384C>G p.P462A (on ENST00000283285 / NM_198196.3; = p.P446A on NM_005816.5) | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- CDC25C | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CDH2 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH9 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 71/350 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK13 | c.2402T>A p.L801Q | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CERKL | c.1645G>T p.G549* (on ENST00000339098 / NM_001030311.2; = p.G523* on NM_201548.5) | Nonsense Mutation (SNP) | VAF 28/132 reads (21%) | called by muse, mutect2, varscan2
- CGA | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CNTNAP5 | c.3582G>T p.L1194F | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COASY | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, varscan2
- COL12A1 | c.5086G>T p.D1696Y | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- COL6A3 | c.3027A>G p.I1009M | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CSMD3 | c.1763A>T p.Q588L (on ENST00000297405 / NM_001363185.1; = p.Q484L on NM_052900.3) | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTNNA2 | c.2295+1G>T p.X765_splice | Splice Site (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- DCAF10 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DDX19A | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- DDX19A | c.1421A>T p.E474V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2
- DGKI | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 48/409 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DIAPH3 | c.2550G>T p.M850I (on ENST00000400324 / NM_001042517.2; = p.M587I on NM_030932.3) | Missense Mutation (SNP) | VAF 121/321 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DLGAP4 | c.862T>A p.Y288N | Missense Mutation (SNP) | VAF 116/358 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAJC13 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.971); called by muse, mutect2
- DSCAM | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DST | c.1294G>T p.G432W (on ENST00000361203 / NM_001374722.1; = p.G106W on NM_001723.6) | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- EMILIN1 | c.853G>T p.G285C | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- EML6 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.752); called by muse, varscan2
- EXOC4 | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM78B | c.342G>T p.W114C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FARS2 | c.1287G>T p.E429D | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FBN2 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCAR | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FCGBP | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FERMT3 | c.602_611del p.P201Hfs*65 | Frame Shift Del (DEL) | VAF 62/178 reads (35%) | called by mutect2, pindel, varscan2
- FREM3 | c.311C>A p.P104Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- FTSJ3 | c.918-4G>C | Splice Region (SNP) | VAF 33/138 reads (24%) | called by muse, mutect2, varscan2
- FYB1 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FYB2 | c.1523G>T p.S508I | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.466); called by muse, mutect2
- FZR1 | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- GALNT13 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GAS2L3 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.707); called by muse, mutect2
- GATA5 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.202); called by muse, mutect2
- GCFC2 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- GCN1 | c.5928G>T p.K1976N | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- GIT2 | c.1339C>A p.L447I | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GJE1 | c.496C>A p.H166N | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GLRB | c.750G>T p.T250= | Splice Region (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- GRAMD1A | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2B | c.1935C>A p.S645R | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GXYLT1 | c.1055G>A p.C352Y | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GYPC | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 71/284 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- GZMA | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR4 | c.2858G>A p.R953H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- HEATR4 | c.2712dup p.R905Tfs*26 | Frame Shift Ins (INS) | VAF 45/272 reads (17%) | called by mutect2, pindel, varscan2
- HECW1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOXA1 | c.115T>G p.S39A | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- HS3ST1 | c.675C>A p.F225L | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HTR7 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IFRD1 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 74/340 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IGKV1D-8 | c.118A>T p.R40* | Nonsense Mutation (SNP) | VAF 23/206 reads (11%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 88/415 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGLV1-40 | c.113C>A p.T38N | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- IGLV3-12 | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 106/598 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS3 | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- IRAK3 | c.124C>A p.R42S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); called by muse, mutect2
- JAG1 | c.3656A>T p.*1219Lext*10 | Nonstop Mutation (SNP) | VAF 103/480 reads (21%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.1134T>A p.N378K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KCNU1 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KIF2B | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KLHL31 | c.1766C>A p.P589H | Missense Mutation (SNP) | VAF 107/463 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- KPTN | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KRT31 | c.1003C>A p.Q335K | Missense Mutation (SNP) | VAF 78/441 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT78 | c.1424G>C p.G475A | Missense Mutation (SNP) | VAF 39/365 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- KRT84 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- LBP | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- LCN9 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCP1 | c.1165del p.A389Lfs*16 | Frame Shift Del (DEL) | VAF 49/183 reads (27%) | called by mutect2, pindel, varscan2
- LCT | c.3463G>T p.A1155S | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LIX1 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- LOXHD1 | c.639C>G p.D213E | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- LRFN2 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 59/306 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1 | c.9008A>G p.Y3003C | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- LRRC4 | c.502A>G p.N168D | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- LRRCC1 | c.282G>T p.L94F | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTB4R2 | c.887C>G p.A296G (on ENST00000528054; = p.A265G on NM_019839.5) | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- LURAP1 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- LZTS3 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MAGEB2 | c.230C>A p.S77* | Nonsense Mutation (SNP) | VAF 78/151 reads (52%) | called by muse, mutect2, varscan2
- MAP3K8 | c.663C>A p.S221R | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MDN1 | c.6861-1G>T p.X2287_splice | Splice Site (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2
- MED1 | c.852-1G>T p.X284_splice | Splice Site (SNP) | VAF 10/88 reads (11%) | called by muse, varscan2
- MED23 | c.3944A>T p.E1315V | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- MPL | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MPP5 | c.8C>G p.T3R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- MSL3 | c.548A>T p.Q183L (on ENST00000312196 / NM_078629.4; = p.Q17L on NM_006800.4) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MTUS1 | c.2935G>T p.E979* (on ENST00000262102 / NM_001363061.1; = p.E145* on NM_020749.4) | Nonsense Mutation (SNP) | VAF 10/253 reads (4%) | called by muse, mutect2
- MUC16 | c.6629A>T p.H2210L | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, varscan2
- MUC16 | c.6444G>C p.M2148I | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, varscan2
- MUC22 | c.2671G>A p.E891K | Missense Mutation (SNP) | VAF 75/339 reads (22%) | SIFT tolerated (0.8); called by muse, mutect2, varscan2
- MYL10 | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 47/248 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- NAA35 | c.2098_2100del p.G700del | In Frame Del (DEL) | VAF 10/80 reads (13%) | called by pindel, varscan2
- NBPF9 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 50/1223 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.261); called by muse, mutect2
- NOS2 | c.3347A>T p.Q1116L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, varscan2
- NRG3 | c.1964T>A p.L655Q (on ENST00000404547 / NM_001370084.1; = p.L631Q on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NTNG2 | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 96/356 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OBSL1 | c.1366G>T p.G456W | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR10J3 | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 47/464 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- OR2AP1 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR2L8 | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- OR2T3 | c.204dup p.S69Qfs*27 | Frame Shift Ins (INS) | VAF 22/160 reads (14%) | called by mutect2, varscan2
- OR2T6 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- OR3A1 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- OR51Q1 | c.854C>G p.A285G | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- OR8D2 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL8 | c.2415A>T p.Q805H | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- OTOF | c.4338_4339del p.E1447Afs*41 (on ENST00000272371 / NM_194248.3; = p.E680Afs*41 on NM_004802.4) | Frame Shift Del (DEL) | VAF 236/634 reads (37%) | called by mutect2, pindel*, varscan2*
- OTOS | c.71T>A p.V24E | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- PADI1 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD3 | c.2152C>G p.L718V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PCDH11Y | c.3680G>T p.S1227I | Missense Mutation (SNP) | VAF 155/316 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PDPR | c.1204T>C p.W402R | Missense Mutation (SNP) | VAF 45/812 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2
- PDZD2 | c.3473G>C p.R1158T | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- PHF14 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF21B | c.1321C>A p.Q441K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIEZO2 | c.4423G>T p.D1475Y | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PIKFYVE | c.2623G>T p.D875Y | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLCD4 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 50/228 reads (22%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.2974G>T p.E992* | Nonsense Mutation (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- POM121L12 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PPFIA3 | c.2321A>T p.K774I | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PPP1R3A | c.1696C>A p.L566M | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- PPP1R3E | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- PPP4R4 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- PREPL | c.1621A>G p.T541A | Missense Mutation (SNP) | VAF 145/540 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- PSG4 | c.1055T>G p.L352W | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PSKH2 | c.533A>T p.Q178L | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSMD1 | c.1898G>T p.C633F | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, varscan2
- PSMD5 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PTPN20 | c.725T>A p.M242K | Missense Mutation (SNP) | VAF 106/559 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRN2 | c.1384C>G p.H462D | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RBM22 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- RFPL1 | c.859A>T p.S287C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- RFXANK | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 51/407 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- RGL1 | c.1906A>G p.T636A (on ENST00000360851 / NM_001297672.2; = p.T671A on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- RIPK4 | c.1444G>C p.A482P (on ENST00000352483; = p.A434P on NM_020639.3) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- RNF135 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 87/366 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ROBO2 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RP1L1 | c.5342C>A p.T1781N | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- RSU1 | c.242A>T p.Q81L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- RYR1 | c.7061T>A p.V2354E | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- RYR2 | c.1565C>A p.A522E | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SATB2 | c.2167A>G p.S723G | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- SCN10A | c.5468C>A p.A1823E | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- SEMA3D | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SENP6 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SERPINB10 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SH2D4B | c.31A>C p.I11L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- SHTN1 | c.1663_1673+1del p.X555_splice | Splice Site (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- SIDT1 | c.602T>C p.I201T | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SIGLEC12 | c.439C>A p.L147I (on ENST00000291707 / NM_053003.4; = p.L29I on NM_033329.2) | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SIPA1L3 | c.3958C>T p.P1320S | Missense Mutation (SNP) | VAF 91/490 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- SIRPA | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 17/482 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC14A2 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC22A15 | c.34del p.E12Rfs*66 | Frame Shift Del (DEL) | VAF 18/159 reads (11%) | called by mutect2, pindel, varscan2
- SLC26A5 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC30A6 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC5A12 | c.1540G>C p.G514R | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SLC8B1 | c.494A>T p.H165L | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2
- SP140 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SPIDR | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.031); called by muse, mutect2
- STAB2 | c.5693C>A p.A1898D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- STOX2 | c.948G>C p.R316S | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- TAMM41 | c.1292T>C p.L431P | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEDDM1 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TEX15 | c.437C>T p.T146I (on ENST00000638951; = p.T142I on NM_001350162.2) | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- TEX55 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- THSD7B | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132B | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM156 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM266 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM63C | c.2314C>A p.P772T | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM67 | c.2374A>G p.R792G | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TPX2 | c.609-2A>T p.X203_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2
- TPX2 | c.609-1G>T p.X203_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2
- TRAPPC9 | c.1684G>T p.G562C | Missense Mutation (SNP) | VAF 98/416 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- TRBC2 | c.269C>G p.P90R | Missense Mutation (SNP) | VAF 86/467 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM1 | c.3950T>C p.V1317A | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSC2 | c.-29-6_-25del | Splice Site (DEL) | VAF 48/188 reads (26%) | called by pindel, varscan2
- TSPAN12 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- TUBA8 | c.946T>G p.C316G | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- UBE2W | c.364A>T p.K122* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- UGT2B4 | c.1010G>C p.W337S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC5A | c.2474C>G p.A825G | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- UPK1A | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 75/161 reads (47%) | called by muse, mutect2, varscan2
- USP9Y | c.4633G>T p.E1545* | Nonsense Mutation (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- WFDC8 | c.214T>A p.C72S | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP57 | c.1066A>G p.R356G | Missense Mutation (SNP) | VAF 123/555 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF155 | c.16-2A>T p.X6_splice | Splice Site (SNP) | VAF 65/182 reads (36%) | called by muse, mutect2, varscan2
- ZNF28 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 48/329 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF311 | c.1736G>C p.G579A | Missense Mutation (SNP) | VAF 77/347 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF331 | c.1154G>A p.C385Y | Missense Mutation (SNP) | VAF 76/359 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF347 | c.1127A>G p.N376S | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF417 | c.1270A>T p.T424S | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF528 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF536 | c.1276C>A p.L426M | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF676 | c.1492A>G p.K498E (on ENST00000650058; = p.K466E on NM_001001411.3) | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF676 | c.1490C>G p.T497S (on ENST00000650058; = p.T465S on NM_001001411.3) | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF71 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ZNF717 | c.1862G>T p.C621F | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF804A | c.2327C>A p.S776* | Nonsense Mutation (SNP) | VAF 50/210 reads (24%) | called by muse, mutect2, varscan2
- ZSWIM2 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACACB | c.6900C>T p.F2300= | Silent (SNP) | VAF 22/184 reads (12%) | called by muse, mutect2, varscan2
- ACTN2 | c.720C>G p.P240= | Silent (SNP) | VAF 61/600 reads (10%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.2964C>T p.I988= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs1349019889, COSV100941755; called by muse, mutect2, varscan2
- ADAMTS15 | c.480G>T p.R160= | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- ADGRL2 | c.1539T>G p.P513= | Silent (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- AFM | c.79C>A p.R27= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV56919726; called by muse, mutect2, varscan2
- ASB15 | c.441C>T p.P147= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as rs140968272; called by muse, mutect2, varscan2
- ATP2C2 | c.2400C>T p.I800= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as rs757287005; called by muse, mutect2, varscan2
- BMPER | c.513G>T p.V171= | Silent (SNP) | VAF 33/353 reads (9%) | called by muse, mutect2
- BRAP | c.531T>A p.L177= | Silent (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- BSN | c.7473G>C p.A2491= | Silent (SNP) | VAF 42/116 reads (36%) | called by muse, mutect2, varscan2
- BSPH1 | c.21C>T p.L7= | Silent (SNP) | VAF 36/165 reads (22%) | catalogued as COSV60413282; called by muse, mutect2, varscan2
- C14orf93 | c.546G>T p.R182= | Silent (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2, varscan2
- CCDC70 | c.63C>G p.S21= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV99665316; called by muse, mutect2, varscan2
- CCM2L | c.519A>T p.A173= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- CD93 | c.1941A>G p.T647= | Silent (SNP) | VAF 44/221 reads (20%) | called by muse, mutect2, varscan2
- CDH18 | c.375G>T p.V125= | Silent (SNP) | VAF 134/409 reads (33%) | catalogued as rs776240500, COSV99939163; called by muse, mutect2, varscan2
- CDK13 | c.2401C>T p.L801= | Silent (SNP) | VAF 16/103 reads (16%) | called by muse, varscan2
- CEP120 | c.30C>T p.I10= | Silent (SNP) | VAF 35/223 reads (16%) | catalogued as COSV60264143; called by muse, mutect2, varscan2
- CEP170B | c.4308G>C p.L1436= (on ENST00000453495; = p.L1365= on NM_015005.3) | Silent (SNP) | VAF 28/222 reads (13%) | called by muse, mutect2, varscan2
- CFAP46 | c.5295G>A p.L1765= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as rs575827463; called by muse, mutect2, varscan2
- CHI3L1 | c.37C>T p.L13= | Silent (SNP) | VAF 63/321 reads (20%) | called by muse, varscan2
- CLVS2 | c.639G>T p.V213= | Silent (SNP) | VAF 32/162 reads (20%) | called by muse, varscan2
- CNTN5 | c.63A>C p.S21= | Silent (SNP) | VAF 48/196 reads (24%) | catalogued as rs769441323; called by muse, varscan2
- CNTNAP2 | c.2196C>T p.I732= | Silent (SNP) | VAF 41/494 reads (8%) | catalogued as rs769830314, COSV62192120, COSV62206510; called by muse, mutect2
- CROCC2 | c.1401C>A p.G467= | Silent (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- CUX1 | c.3219G>T p.L1073= | Silent (SNP) | VAF 74/292 reads (25%) | catalogued as COSV52904233; called by muse, mutect2, varscan2
- DDX42 | c.1776G>T p.A592= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as COSV63791180; called by muse, mutect2, varscan2
- DIS3 | c.1038A>G p.V346= | Silent (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- DNER | c.804C>A p.V268= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as COSV100519767, COSV59160460; called by muse, mutect2, varscan2
- DOK3 | c.930G>A p.P310= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs776970735; called by muse, mutect2, varscan2
- DPY19L2 | c.1668A>T p.L556= | Silent (SNP) | VAF 14/151 reads (9%) | catalogued as COSV61046844; called by muse, mutect2
- DZANK1 | c.33C>T p.I11= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- EIF3A | c.2178G>A p.E726= | Silent (SNP) | VAF 48/224 reads (21%) | called by muse, mutect2, varscan2
- FBN2 | c.7383C>A p.T2461= | Silent (SNP) | VAF 76/225 reads (34%) | called by muse, mutect2, varscan2
- FLNA | c.570G>C p.R190= | Silent (SNP) | VAF 51/142 reads (36%) | called by muse, mutect2, varscan2
- FLT4 | c.1350G>T p.V450= | Silent (SNP) | VAF 49/219 reads (22%) | catalogued as COSV56101565; called by muse, mutect2, varscan2
- FRMD4A | c.2694G>A p.P898= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs758111344; called by mutect2, varscan2
- FSHR | c.768T>A p.P256= | Silent (SNP) | VAF 132/411 reads (32%) | called by muse, mutect2, varscan2
- GABRB2 | c.1035T>A p.A345= | Silent (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- GBGT1 | c.930G>T p.P310= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs781139468, COSV64410153; called by muse, mutect2, varscan2
- GHR | c.1332G>A p.Q444= | Silent (SNP) | VAF 34/366 reads (9%) | called by muse, mutect2
- GLI1 | c.837G>A p.L279= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- GRM8 | c.2187G>A p.R729= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs377654541; called by muse, varscan2
- HIF3A | c.234G>T p.V78= (on ENST00000377670 / NM_152795.4; = p.V76= on NM_152794.4) | Silent (SNP) | VAF 38/169 reads (22%) | called by muse, mutect2, varscan2
- HK2 | c.1524C>T p.P508= | Silent (SNP) | VAF 24/201 reads (12%) | catalogued as rs142174869; called by muse, mutect2, varscan2
- HLA-DPA1 | c.72G>T p.L24= | Silent (SNP) | VAF 50/226 reads (22%) | called by muse, mutect2, varscan2
- HMCN1 | c.6309G>A p.P2103= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as rs367790421, COSV99621889; called by muse, mutect2, varscan2
- HRH2 | c.744T>C p.F248= | Silent (SNP) | VAF 51/486 reads (10%) | called by muse, mutect2, varscan2
- IFT122 | c.1716A>G p.G572= (on ENST00000348417 / NM_052989.3; = p.G513= on NM_018262.4) | Silent (SNP) | VAF 55/561 reads (10%) | called by muse, mutect2, varscan2
- IGLON5 | c.564C>T p.G188= | Silent (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- IL18RAP | c.231C>T p.N77= | Silent (SNP) | VAF 82/354 reads (23%) | catalogued as rs764677669, COSV51825194; called by muse, mutect2, varscan2
- IL1RL1 | c.405C>A p.T135= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- IRGC | c.150G>A p.T50= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as rs775944512, COSV54983077; called by muse, mutect2, varscan2
- KCNK12 | c.960C>G p.R320= | Silent (SNP) | VAF 40/120 reads (33%) | called by muse, varscan2
- KEL | c.324T>C p.C108= | Silent (SNP) | VAF 40/470 reads (9%) | catalogued as rs371883953; called by muse, mutect2
- KIF2B | c.478C>A p.R160= | Silent (SNP) | VAF 45/186 reads (24%) | catalogued as rs181862662; called by muse, mutect2, varscan2
- KNDC1 | c.2184G>T p.T728= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2
- KRT82 | c.163C>A p.R55= | Silent (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- KRTAP13-2 | c.60C>A p.R20= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as rs900426614; called by muse, mutect2, varscan2
- MAGEB18 | c.444C>A p.I148= | Silent (SNP) | VAF 61/128 reads (48%) | catalogued as COSV57464803; called by muse, mutect2, varscan2
- MDH2 | c.270G>C p.L90= | Silent (SNP) | VAF 23/259 reads (9%) | called by muse, mutect2
- MS4A2 | c.303A>G p.P101= | Silent (SNP) | VAF 69/210 reads (33%) | called by muse, mutect2, varscan2
- MTMR11 | c.1251C>T p.P417= (on ENST00000439741 / NM_001145862.2; = p.P345= on NM_181873.3) | Silent (SNP) | VAF 26/416 reads (6%) | catalogued as COSV54967157; called by muse, mutect2
- MUC16 | c.38106C>A p.T12702= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- MUC17 | c.4890T>C p.S1630= | Silent (SNP) | VAF 22/196 reads (11%) | catalogued as COSV60287945; called by muse, mutect2, varscan2
- MUC5AC | c.1680G>T p.A560= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV62253618; called by muse, mutect2, varscan2
- MUC5AC | c.13455C>A p.P4485= | Silent (SNP) | VAF 158/544 reads (29%) | called by muse, varscan2
- NCAM1 | c.1041C>T p.N347= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs370947557; called by muse, mutect2, varscan2
- NGB | c.100C>T p.L34= | Silent (SNP) | VAF 54/197 reads (27%) | catalogued as rs1198275510; called by muse, mutect2, varscan2
- NKAIN1 | c.381G>T p.L127= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- NUTM2G | c.213C>A p.R71= | Silent (SNP) | VAF 74/229 reads (32%) | catalogued as COSV100672873; called by muse, mutect2, varscan2
- OAS3 | c.129C>T p.R43= | Silent (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- OR10K1 | c.261C>A p.S87= | Silent (SNP) | VAF 274/527 reads (52%) | catalogued as COSV56871393; called by muse, mutect2, varscan2
- OR2D2 | c.816G>T p.V272= | Silent (SNP) | VAF 95/240 reads (40%) | called by muse, mutect2, varscan2
- OR2M7 | c.63C>T p.S21= | Silent (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- OR5AP2 | c.297T>C p.S99= | Silent (SNP) | VAF 9/187 reads (5%) | catalogued as COSV57258207; called by muse, mutect2
- OR5F1 | c.579C>T p.I193= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV53545369, COSV53547790; called by muse, mutect2, varscan2
- OR6C3 | c.60T>A p.L20= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as rs759166933; called by muse, mutect2
- OTUD6A | c.39C>A p.R13= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV57972501; called by muse, mutect2, varscan2
- P2RY8 | c.76C>T p.L26= | Silent (SNP) | VAF 65/217 reads (30%) | called by muse, mutect2, varscan2
- PAK3 | c.1095G>A p.L365= (on ENST00000262836 / NM_001324328.2; = p.L350= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- PCDH15 | c.3522C>A p.G1174= | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as rs753725514; ClinVar: likely benign; called by muse, varscan2
- PCDHB9 | c.231G>T p.L77= | Silent (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.888C>T p.D296= | Silent (SNP) | VAF 56/179 reads (31%) | called by muse, mutect2, varscan2
- PCOLCE | c.1149C>T p.Y383= | Silent (SNP) | VAF 18/177 reads (10%) | catalogued as rs556143471, COSV56158074; called by muse, mutect2, varscan2
- PCSK5 | c.2355C>T p.C785= | Silent (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- PIEZO2 | c.2454C>A p.L818= | Silent (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- PLXNA1 | c.4215A>T p.T1405= | Silent (SNP) | VAF 71/325 reads (22%) | called by muse, mutect2, varscan2
- POFUT1 | c.1140G>A p.R380= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as rs923458752; called by muse, mutect2, varscan2
- POMC | c.142C>A p.R48= | Silent (SNP) | VAF 104/260 reads (40%) | called by muse, mutect2, varscan2
- PYM1 | c.117G>A p.Q39= | Silent (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- RGPD3 | c.5106G>A p.E1702= | Silent (SNP) | VAF 107/573 reads (19%) | catalogued as rs753704277; called by muse, mutect2, varscan2
- RIC1 | c.108G>T p.V36= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs1373222912; called by muse, mutect2, varscan2
- RIC3 | c.264A>C p.G88= | Silent (SNP) | VAF 166/398 reads (42%) | called by muse, mutect2, varscan2
- RYR2 | c.2196C>A p.L732= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV63678562; called by muse, mutect2
- SALL3 | c.714G>A p.P238= | Silent (SNP) | VAF 50/182 reads (27%) | catalogued as rs1432856818, COSV73306076; called by muse, mutect2, varscan2
- SALL3 | c.3402G>T p.T1134= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as COSV101609936; called by muse, mutect2, varscan2
- SEPTIN9 | c.1536G>A p.R512= (on ENST00000427177 / NM_001113491.2; = p.R494= on NM_006640.4) | Silent (SNP) | VAF 26/301 reads (9%) | catalogued as rs756265056; called by muse, mutect2
- SETD6 | c.855T>C p.Y285= (on ENST00000219315 / NM_001160305.4; = p.Y261= on NM_024860.3) | Silent (SNP) | VAF 45/468 reads (10%) | catalogued as rs181707932; called by muse, mutect2
- SIGLEC14 | c.444C>A p.I148= | Silent (SNP) | VAF 41/288 reads (14%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.1062G>C p.G354= | Silent (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- SLC1A3 | c.1407C>T p.I469= | Silent (SNP) | VAF 39/407 reads (10%) | catalogued as COSV54314214; called by muse, mutect2
- SLC35C1 | c.54G>T p.G18= | Silent (SNP) | VAF 103/244 reads (42%) | catalogued as COSV58479850; called by muse, mutect2, varscan2
- SLC6A2 | c.1332C>A p.L444= | Silent (SNP) | VAF 61/289 reads (21%) | called by muse, mutect2, varscan2
- SUGCT | c.1116G>A p.E372= (on ENST00000335693 / NM_001193313.2; = p.E398= on NM_024728.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as COSV59319394; called by muse, mutect2
- SULF2 | c.276C>A p.R92= | Silent (SNP) | VAF 158/554 reads (29%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.435C>A p.T145= | Silent (SNP) | VAF 65/228 reads (29%) | catalogued as COSV65236036; called by muse, mutect2, varscan2
- TBCE | c.804A>G p.L268= (on ENST00000366601; = p.L331= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/502 reads (9%) | called by muse, mutect2
- TMPRSS11E | c.1140A>T p.S380= | Silent (SNP) | VAF 10/74 reads (14%) | called by muse, varscan2
- TOX | c.39C>T p.A13= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs1237627375; called by muse, mutect2, varscan2
- TPCN1 | c.903C>T p.I301= | Silent (SNP) | VAF 28/308 reads (9%) | catalogued as rs1238385116; called by muse, mutect2
- UBE2O | c.1383C>G p.P461= | Silent (SNP) | VAF 56/235 reads (24%) | called by muse, mutect2, varscan2
- UNC80 | c.4950G>T p.T1650= | Silent (SNP) | VAF 43/216 reads (20%) | catalogued as COSV55900339; called by muse, mutect2, varscan2
- UPK3A | c.693C>A p.A231= | Silent (SNP) | VAF 88/270 reads (33%) | called by muse, mutect2, varscan2
- VAV1 | c.1623T>C p.Y541= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs1179486351; called by muse, mutect2, varscan2
- VWA5B1 | c.3111T>A p.A1037= (on ENST00000375079; = p.A1032= on NM_001039500.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/121 reads (28%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1695G>C p.V565= | Silent (SNP) | VAF 40/239 reads (17%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.6492C>G p.L2164= | Silent (SNP) | VAF 46/485 reads (9%) | called by muse, mutect2
- ZNF275 | c.147G>T p.A49= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100936086; called by muse, mutect2, varscan2
- ZNF347 | c.1935C>A p.V645= | Silent (SNP) | VAF 40/179 reads (22%) | called by mutect2, varscan2
- ZNF536 | c.1509C>T p.I503= | Silent (SNP) | VAF 63/171 reads (37%) | catalogued as COSV62818539; called by muse, mutect2, varscan2
- ZNF570 | c.132A>T p.L44= | Silent (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- AC078880.2 | n.368dup | RNA (INS) | VAF 17/127 reads (13%) | called by mutect2, pindel
- ACSF2 | c.129-432A>G | Intron (SNP) | VAF 28/139 reads (20%) | called by muse, mutect2, varscan2
- ADAM21P1 | n.1882T>A | RNA (SNP) | VAF 34/197 reads (17%) | called by muse, mutect2, varscan2
- ADAM21P1 | n.1881C>G | RNA (SNP) | VAF 33/194 reads (17%) | catalogued as rs1351932691; called by muse, mutect2, varscan2
- AKNAD1 | c.2167+105C>A | Intron (SNP) | VAF 10/77 reads (13%) | catalogued as rs188602539; called by muse, mutect2, varscan2
- AL121757.1 | n.443C>G | RNA (SNP) | VAF 12/418 reads (3%) | called by muse, mutect2
- ANO6 | c.71-31535A>T | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- ATM | c.4436+15_4436+25del | Intron (DEL) | VAF 25/123 reads (20%) | called by mutect2, pindel, varscan2
- C14orf177 | n.508G>T | RNA (SNP) | VAF 49/270 reads (18%) | catalogued as COSV100362743; called by muse, mutect2, varscan2
- CASK | c.-47C>T | 5'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, varscan2
- CHD5 | c.*3383G>A | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- COPZ1 | c.-30G>T | 5'UTR (SNP) | VAF 62/241 reads (26%) | catalogued as rs1401364908; called by muse, mutect2, varscan2
- CYP11B1 | c.239+157G>T | Intron (SNP) | VAF 51/231 reads (22%) | called by muse, mutect2, varscan2
- DCHS2 | n.2653-755A>T | Intron (SNP) | VAF 26/119 reads (22%) | called by muse, mutect2, varscan2
- DPP9 | c.2092-141G>T | Intron (SNP) | VAF 38/168 reads (23%) | catalogued as rs781362350; called by muse, mutect2, varscan2
- EIF4G1 | c.-34-9del | Intron (DEL) | VAF 31/131 reads (24%) | called by mutect2, pindel, varscan2
- EME2 | c.570-27C>T | Intron (SNP) | VAF 96/274 reads (35%) | catalogued as rs138651735; called by muse, mutect2, varscan2
- FAM90A20P | n.982C>A | RNA (SNP) | VAF 206/729 reads (28%) | called by muse, mutect2, varscan2
- FOXRED1 | c.86-46G>T | Intron (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- GM2A | c.-28T>C | 5'UTR (SNP) | VAF 29/183 reads (16%) | called by muse, mutect2, varscan2
- GPR89B | chr1:147995598 G>T | 3'Flank (SNP) | VAF 195/448 reads (44%) | called by muse, mutect2, varscan2
- GUSBP10 | n.119C>A | RNA (SNP) | VAF 34/224 reads (15%) | called by muse, mutect2, varscan2
- IGBP1 | c.679-36G>T | Intron (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- KLHL3 | c.904-7654G>T | Intron (SNP) | VAF 24/92 reads (26%) | catalogued as COSV100553187; called by muse, mutect2, varscan2
- KRT6A | c.913-46G>T | Intron (SNP) | VAF 54/447 reads (12%) | called by muse, mutect2, varscan2
- LGSN | c.163+1158G>T | Intron (SNP) | VAF 49/179 reads (27%) | called by muse, mutect2, varscan2
- LINC02724 | n.553C>T | RNA (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2, varscan2
- LMBR1 | c.*2968A>G | 3'UTR (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- LOXL3 | c.*616T>A | 3'UTR (SNP) | VAF 21/164 reads (13%) | called by muse, mutect2, varscan2
- MGAM | c.4619-9990G>A | Intron (SNP) | VAF 27/127 reads (21%) | catalogued as rs772366664; called by muse, mutect2, varscan2
- MIR372 | n.54C>T | RNA (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- MIR520C | n.63C>A | RNA (SNP) | VAF 27/119 reads (23%) | catalogued as rs752004846; called by muse, mutect2, varscan2
- MOGAT3 | c.872-12C>A | Intron (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
- MRNIP | chr5:179860535 G>A | 5'Flank (SNP) | VAF 64/295 reads (22%) | catalogued as rs73335958; called by muse, mutect2, varscan2
- MTA3 | c.190+2645C>T | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- MYADML | n.528G>C | RNA (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- NBAS | c.6712-31G>T | Intron (SNP) | VAF 36/280 reads (13%) | called by muse, varscan2
- NDRG4 | c.373-48C>A | Intron (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- NPIPB10P | n.21C>A | RNA (SNP) | VAF 63/423 reads (15%) | called by muse, varscan2
- NPR3 | chr5:32710735 C>T | 5'Flank (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- OR2W5 | n.979C>G | RNA (SNP) | VAF 121/344 reads (35%) | called by muse, mutect2, varscan2
- OR5E1P | n.433G>C | RNA (SNP) | VAF 51/130 reads (39%) | called by muse, mutect2, varscan2
- PCBP2 | c.1061+3312A>G | Intron (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- PLCH2 | c.2959+233G>T | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- POLR2F | c.452+1005C>T | Intron (SNP) | VAF 11/61 reads (18%) | called by muse, varscan2
- RNF217-AS1 | n.2946G>T | RNA (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.354G>T | RNA (SNP) | VAF 27/135 reads (20%) | catalogued as rs766072686; called by muse, mutect2, varscan2
- SAP30 | c.*3G>T | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- SHH | c.-41C>A | 5'UTR (SNP) | VAF 62/242 reads (26%) | called by muse, mutect2, varscan2
- SLC29A3 | c.*596A>G | 3'UTR (SNP) | VAF 7/126 reads (6%) | called by muse, mutect2
- SLC2A1 | c.-23A>T | 5'UTR (SNP) | VAF 74/268 reads (28%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44080G>T | Intron (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- SNORD114-29 | n.46A>T | RNA (SNP) | VAF 24/113 reads (21%) | called by muse, varscan2
- TBXAS1 | c.-79-152A>G | Intron (SNP) | VAF 23/124 reads (19%) | catalogued as rs150958431; called by muse, mutect2, varscan2
- TEX35 | c.586+386C>A | Intron (SNP) | VAF 29/198 reads (15%) | catalogued as rs766448863, COSV99274738; called by muse, mutect2, varscan2
- TFF2 | c.*81A>G | 3'UTR (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- TRAPPC2L | c.-21C>A | 5'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, varscan2
- TSBP1 | c.257-34G>T | Intron (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100898945; called by muse, mutect2, varscan2
- TUSC3 | c.1028+348G>T | Intron (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- USE1 | c.422+18dup | Intron (INS) | VAF 20/116 reads (17%) | called by mutect2, pindel, varscan2
- USP43 | c.1663-34G>T | Intron (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- VAPB | c.*3423del | 3'UTR (DEL) | VAF 119/386 reads (31%) | called by mutect2, varscan2*
- VAPB | c.*3425_*3431del | 3'UTR (DEL) | VAF 121/395 reads (31%) | called by mutect2, varscan2*
- VMA21 | c.-39A>C | 5'UTR (SNP) | VAF 50/80 reads (63%) | called by muse, mutect2, varscan2
- VPS11 | c.-830C>T | 5'UTR (SNP) | VAF 28/281 reads (10%) | called by muse, mutect2, varscan2
- WSB2 | c.14-19A>G | Intron (SNP) | VAF 35/110 reads (32%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451250 G>T | 5'Flank (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
